Somatic mutation profile of tumor specimen C3N-03620-02 (aliquot CPT0196040009) from CPTAC case C3N-03620, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.0 years (22,641 days).
Specimen C3N-03620-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 555a1b2a-6577-4b21-b249-e2539d77fcff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03620-71 (Blood Derived Normal), aliquot CPT0196150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6be4c9de-c7d9-4394-8458-99adf046dc69

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Intron 3, Nonsense Mutation 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 110/1104 reads (10%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2
- C2orf16 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs1260128687, COSV62676761; called by muse, mutect2
- CNNM3 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1307719642; called by muse, mutect2
- EIF2AK3 | c.2717T>C p.I906T | Missense Mutation (SNP) | VAF 31/605 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs1452006499; called by muse, mutect2
- KCNS3 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs17851366; called by muse, mutect2
- KIF26A | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 29/591 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767575760; called by muse, mutect2
- LRP1 | c.13598G>A p.R4533Q | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1031302605, COSV99675881; called by muse, mutect2
- OR2T4 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 24/874 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV100822591; called by muse, mutect2
- PLA2G2E | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 27/457 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.091); catalogued as rs775498456, COSV100908835, COSV64290450; called by muse, mutect2
- POLD3 | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 17/445 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1361821756; called by muse, mutect2
- RNF186 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 26/455 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV64296738; called by muse, mutect2
- C1orf43 | c.178G>A p.E60K (on ENST00000368521 / NM_001297718.2; = p.E26K on NM_015449.4) | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2
- CCDC158 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- DPYS | c.1444-3C>T | Splice Region (SNP) | VAF 15/484 reads (3%) | called by muse, mutect2
- ERAS | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- HERC1 | c.13091C>T p.P4364L | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2
- MAGED1 | c.45+1G>C p.X15_splice | Splice Site (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- NRP1 | c.1614+3G>A | Splice Region (SNP) | VAF 12/313 reads (4%) | called by muse, mutect2
- ODF2 | c.1861G>A p.E621K (on ENST00000434106 / NM_153433.2; = p.E597K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/906 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PGM5 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2
- POU6F2 | c.1123C>T p.L375F | Missense Mutation (SNP) | VAF 24/735 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMC1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 30/702 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CSPG4 | c.2913C>T p.V971= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- CTNND2 | c.318A>T p.S106= | Silent (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- DACT3 | c.762G>A p.S254= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- HTT | c.1149C>T p.L383= | Silent (SNP) | VAF 26/704 reads (4%) | called by muse, mutect2
- MYO15A | c.2037G>A p.P679= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs1267617969; called by muse, mutect2, varscan2
- MYO7A | c.5379C>T p.N1793= | Silent (SNP) | VAF 15/275 reads (5%) | catalogued as rs546027035; called by muse, mutect2
- ADAMTS6 | c.1370+2792G>A | Intron (SNP) | VAF 8/214 reads (4%) | catalogued as rs1484592014; called by muse, mutect2
- UBE2V2 | c.16+36C>T | Intron (SNP) | VAF 24/674 reads (4%) | called by muse, mutect2
- VPS41 | c.2404+127G>T | Intron (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
